Somatic mutation profile of tumor specimen TARGET-10-PARPIF-09A (aliquot TARGET-10-PARPIF-09A-01D) from TARGET case TARGET-10-PARPIF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,900 days).
Specimen TARGET-10-PARPIF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ac238ef-b842-43b1-8e7d-e894cb375704.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPIF-10A (Blood Derived Normal), aliquot TARGET-10-PARPIF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bc07e81-151d-4236-b551-7109df13b2d8

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Splice Site 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIR3DL1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs779002817, COSV58491658; called by muse, mutect2
- MYC | c.175C>T p.P59S (on ENST00000377970; = p.P74S on NM_002467.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52367409, COSV52367643, COSV52370791; called by muse, mutect2
- PKP4 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as rs766638824, COSV67676884; called by muse, mutect2, varscan2
- PRKAA2 | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs200975038; called by muse, mutect2, varscan2
- RYR1 | c.9673C>T p.R3225W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766665861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSTN3 | c.1175A>C p.E392A | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- INPP5B | c.2633G>T p.S878I (on ENST00000373023; = p.S798I on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- MYOM1 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.044); called by muse, mutect2
- NBEAL1 | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHBDL2 | c.247-1G>T p.X83_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- TMEM151A | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TUT7 | c.2694G>T p.E898D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- UNC93B1 | c.827_828insCCTCGG p.L276_R277insLG | In Frame Ins (INS) | VAF 64/173 reads (37%) | called by mutect2, pindel, varscan2
- HCN1 | c.1095C>A p.A365= | Silent (SNP) | VAF 78/167 reads (47%) | catalogued as COSV57510611; called by muse, mutect2, varscan2
- MAGED2 | c.1593C>A p.I531= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV54496933; called by muse, mutect2
- RNF128 | c.231T>C p.A77= | Silent (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- TMEM196 | c.483C>T p.T161= | Silent (SNP) | VAF 56/119 reads (47%) | catalogued as rs766938932; called by muse, varscan2
- ZCCHC9 | c.504C>A p.T168= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1192654448; called by muse, mutect2
- NUP54 | c.67+700G>T | Intron (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
